Somatic mutation profile of tumor specimen 1105244 (aliquot 7316UP-2843-1105244) from CPTAC case C846363, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105244: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6becb83b-7431-4976-b4de-dee071130332.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105216 (Blood Derived Normal), aliquot 7316UP-2100-1105216; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73600138-6d5c-430a-b38c-168d06986756

The open-access MAF lists 88 somatic variants for this specimen: 65 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Nonsense Mutation 4, Frame Shift Del 3, Intron 3, Frame Shift Ins 2, 5'UTR 2, Splice Region 1, 3'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG12 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 64/726 reads (9%) | PolyPhen probably damaging (1); catalogued as rs553349150; called by muse, mutect2
- ANK1 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 62/201 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs764141047, COSV55886773; called by muse, mutect2, varscan2
- CABP2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs375360165, COSV53708769; called by muse, mutect2, varscan2
- CCDC63 | c.1454G>A p.W485* | Nonsense Mutation (SNP) | VAF 23/204 reads (11%) | catalogued as rs750494632; called by muse, mutect2, varscan2
- CD163L1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs779416105, COSV58016469; called by muse, mutect2, varscan2
- CDS1 | c.642C>T p.F214= | Splice Region (SNP) | VAF 7/48 reads (15%) | catalogued as rs375840719; called by muse, mutect2, varscan2
- CHP2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs756989190, COSV55649492; called by muse, mutect2, varscan2
- DDX19B | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.812); catalogued as rs1342443178; called by muse, mutect2, varscan2
- DEFB114 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs141697166, COSV59038413; called by muse, mutect2, varscan2
- DSC2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs374707462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.3691C>T p.P1231S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.975); catalogued as COSV101260742; called by muse, mutect2
- DSP | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 199/723 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs777847026; called by muse, mutect2, varscan2
- KEL | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 23/386 reads (6%) | catalogued as COSV100787323; called by muse, mutect2
- KMT2D | c.7864G>A p.D2622N | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs760968358; called by muse, mutect2, varscan2
- LARP1B | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs150798326; called by muse, mutect2, varscan2
- LRGUK | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs764953610, COSV53633892; called by muse, mutect2, varscan2
- LRP1B | c.12207C>G p.N4069K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV67257448; called by muse, mutect2
- MMP3 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as rs149156238; called by muse, mutect2, varscan2
- MRGPRX4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778327061, COSV58589894; called by muse, mutect2, varscan2
- NIPSNAP2 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753851867; called by muse, mutect2, varscan2
- OR7C1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs772802995, COSV50183672; called by muse, mutect2, varscan2
- PFAS | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 48/217 reads (22%) | catalogued as rs368793879; called by muse, mutect2, varscan2
- PIK3R1 | c.1915C>T p.R639* (on ENST00000521381 / NM_181523.3; = p.R369* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV57126125; called by muse, mutect2, varscan2
- TLR4 | c.2372G>A p.R791K (on ENST00000355622 / NM_138554.5; = p.R751K on NM_003266.4) | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV100842898; called by muse, mutect2, varscan2
- TTN | c.87049G>A p.E29017K (on ENST00000591111; = p.E21593K on NM_003319.4) | Missense Mutation (SNP) | VAF 29/109 reads (27%) | PolyPhen probably damaging (0.994); catalogued as COSV60229470; called by muse, mutect2, varscan2
- AC005324.2 | c.1080_1084del p.E361Qfs*12 | Frame Shift Del (DEL) | VAF 33/304 reads (11%) | called by mutect2, pindel, varscan2
- AC013489.1 | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ASB2 | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CMSS1 | c.350del p.L117Rfs*12 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel
- DOCK3 | c.4613A>G p.N1538S | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); called by muse, mutect2
- EYA1 | c.482C>G p.T161R | Missense Mutation (SNP) | VAF 132/425 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- FHAD1 | c.1712C>A p.A571D | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FRS3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRS3 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FUT8 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.53); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMCL2 | c.846G>C p.W282C | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2
- HCAR3 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- IGSF9 | c.357dup p.D120Rfs*5 | Frame Shift Ins (INS) | VAF 28/224 reads (13%) | called by mutect2, pindel, varscan2
- KRT74 | c.47T>A p.F16Y | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- LILRA5 | c.313del p.S105Pfs*2 | Frame Shift Del (DEL) | VAF 71/611 reads (12%) | called by mutect2, pindel, varscan2
- MGAM2 | c.4807G>T p.D1603Y | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NPDC1 | c.910C>G p.P304A | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- OR2B11 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T10 | c.319T>G p.L107V | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- OR4Q3 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOA | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PCDHGB3 | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2
- PGC | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.027); called by muse, mutect2
- PRKDC | c.11884C>T p.R3962W | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN23 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RNF207 | c.1487G>C p.W496S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- RTF1 | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SHISA6 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SLC38A1 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLCO5A1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- SLIT2 | c.3718T>G p.F1240V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SPATA31E1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TACC1 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TENT4B | c.1160dup p.L388Pfs*25 (on ENST00000561678 / NM_001365323.2; = p.L373Pfs*25 on NM_001040284.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 29/286 reads (10%) | called by mutect2, pindel, varscan2
- TRUB1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.27314G>A p.G9105D (on ENST00000591111; = p.G8178D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/238 reads (26%) | PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- USP6 | c.125A>C p.N42T | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- XIRP1 | c.3596G>T p.C1199F | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF174 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ZNF507 | c.1772T>C p.I591T | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM18 | c.1164A>G p.Q388= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- ARHGAP32 | c.5808A>G p.R1936= (on ENST00000310343 / NM_001378025.1; = p.R1587= on NM_014715.4) | Silent (SNP) | VAF 68/292 reads (23%) | called by muse, mutect2, varscan2
- FGF6 | c.591G>A p.P197= | Silent (SNP) | VAF 60/196 reads (31%) | catalogued as rs776204115; called by muse, mutect2, varscan2
- GOT1L1 | c.198G>A p.L66= | Silent (SNP) | VAF 22/199 reads (11%) | called by muse, mutect2, varscan2
- KRTAP13-2 | c.204G>A p.T68= | Silent (SNP) | VAF 46/161 reads (29%) | catalogued as rs746030923; called by muse, mutect2, varscan2
- LY86 | c.69T>A p.G23= | Silent (SNP) | VAF 31/232 reads (13%) | called by muse, mutect2, varscan2
- NXF1 | c.1473G>C p.L491= | Silent (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- PKP2 | c.2070C>T p.I690= | Silent (SNP) | VAF 81/324 reads (25%) | catalogued as rs538127756, COSV50755620; called by muse, mutect2, varscan2
- SENP3 | c.1455T>C p.R485= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as rs1381389986; called by muse, mutect2, varscan2
- SLC1A7 | c.375G>A p.T125= | Silent (SNP) | VAF 37/362 reads (10%) | catalogued as rs371121273; called by muse, mutect2, varscan2
- SLC4A10 | c.315C>T p.T105= | Silent (SNP) | VAF 39/179 reads (22%) | catalogued as rs374865086; called by muse, mutect2, varscan2
- SYNDIG1L | c.705C>T p.N235= | Silent (SNP) | VAF 98/308 reads (32%) | catalogued as rs764855912, COSV100526538; called by muse, mutect2, varscan2
- TAAR9 | c.519C>T p.N173= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs372695882, COSV71512268; called by muse, mutect2, varscan2
- TTN | c.13209C>T p.T4403= (on ENST00000591111; = p.T4357= on NM_003319.4) | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- TUBA4A | c.162T>C p.C54= | Silent (SNP) | VAF 31/346 reads (9%) | called by muse, mutect2
- AIP | c.*34C>T | 3'UTR (SNP) | VAF 32/316 reads (10%) | called by muse, mutect2
- DPF3 | chr14:72894105 del AG | 5'Flank (DEL) | VAF 33/110 reads (30%) | catalogued as rs766420993; called by mutect2, pindel*, varscan2
- FAM197Y1 | n.374G>A | RNA (SNP) | VAF 27/652 reads (4%) | catalogued as rs776135058; called by muse, mutect2
- GALNT9 | c.1077+270G>A | Intron (SNP) | VAF 44/144 reads (31%) | catalogued as rs1429858126; called by muse, mutect2, varscan2
- GPI | c.123-349G>A | Intron (SNP) | VAF 44/378 reads (12%) | called by muse, mutect2, varscan2
- MSH2 | c.-19G>C | 5'UTR (SNP) | VAF 74/444 reads (17%) | catalogued as rs1237109405; called by muse, mutect2, varscan2
- PPP4R3A | c.1266+21T>G | Intron (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- PRKCG | c.-132C>A | 5'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
